Somatic mutation profile of tumor specimen TCGA-FE-A3PC-01A (aliquot TCGA-FE-A3PC-01A-11D-A21Z-08) from TCGA case TCGA-FE-A3PC, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.8 years (13,817 days).
Specimen TCGA-FE-A3PC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 452be2e4-1dff-4d55-ab98-65b267d92b2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A3PC-10A (Blood Derived Normal), aliquot TCGA-FE-A3PC-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42648e4-37d1-4744-bb4b-3282bea96229

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 12/102 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADGRL3 | c.838G>T p.V280L (on ENST00000506720 / NM_001322402.2; = p.V212L on NM_015236.6) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV72265423; called by muse, mutect2
- COL2A1 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV61527631; called by muse, mutect2
- ETS1 | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60091670; called by muse, mutect2
- MYBPC2 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV63093215; called by muse, mutect2
- MYO1D | c.1453T>A p.F485I | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59006844; called by muse, mutect2
- OR5AS1 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV57980635; called by muse, mutect2, varscan2
- SLAMF8 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV56987412; called by muse, mutect2, varscan2
- TEX101 | c.727C>A p.P243T (on ENST00000598265 / NM_001130011.3; = p.P261T on NM_031451.4) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); catalogued as COSV53661091; called by muse, mutect2, varscan2
- TUBB2B | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV52533113; called by muse, mutect2, varscan2
- ZNF500 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772622536, COSV54786909; called by muse, mutect2, varscan2
- DNM2 | c.1734C>T p.G578= (on ENST00000355667 / NM_001005360.3; = p.G574= on NM_004945.3) | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as rs765544231, COSV58956893; called by muse, mutect2, varscan2
- FNBP1L | c.84T>C p.Y28= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53091076, COSV53096091; called by muse, mutect2, varscan2
- PPP1R8 | c.792C>T p.Y264= (on ENST00000311772 / NM_014110.5; = p.Y40= on NM_002713.4) | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs767947627, COSV52579317; called by muse, mutect2
